Surgical pathology report (de-identified scan), TCGA case TCGA-50-6595, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-6595-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Lung cancer.

PROCEDURE: Right upper lobectomy.

SPECIFIC CLINICAL QUESTION: None given.

OUTSIDE TISSUE DIAGNOSIS: None given.

PRIOR MALIGNANCY: None given.

CHEMORADIATION THERAPY: None given.

ORGAN TRANSPLANT: None given.

IMMUNOSUPPRESSION: None given.

OTHER DISEASES: Yes, [REDACTED]

CYTOGENETIC TESTS: Not given.

ADDENDA:

Addendum

Collection Date: [REDACTED]

Molecular Anatomic Pathology Testing:

Block 2H:

- A. *EGFR* amplification IDENTIFIED (see In Situ Procedure).
- B. *KRAS* codon 12/13 mutation NOT identified.
- C. *EGFR* Exon 19 mutation NOT identified.
- D. *EGFR* Exon 21 mutation NOT identified.
- E. *EML4/ALK* rearrangement NOT identified (see In Situ Procedure).

Note:

KRAS codon 12/13 mutations are found in approximately 10-30% lung adenocarcinomas and associated with history of smoking. The presence of *KRAS* mutation leads to resistance to *EGFR* targeted therapies (1). *EGFR* exon 19 and 21 mutations are present in about 10% of [REDACTED] and up to 40% in the [REDACTED] population, common in [REDACTED] and associated with the clinical response to treatment with *EGFR* inhibitors (2). These mutations are mutually exclusive and their presence may have prognostic and/or therapeutic implications (3,4). Clinical studies show high *EGFR* gene copy number by FISH analysis (amplification) to be associated with favorable clinical benefit (clinical response, stable disease, time to progression, and survival) in patients with advanced non-small cell lung cancer treated with *EGFR* tyrosine kinase inhibitors.

Approximately 3% of lung adenocarcinomas within the Asian population have an interstitial deletion and inversion in chromosome 2p resulting in the *EML4/ALK* fusion gene (*ALK*+) which is sensitive to *ALK* inhibitors (5,6). The prevalence of this abnormality in the Western population is still unknown. Detection of this abnormality is critical for identifying patients eligible for therapies that target *ALK* enzymatic activity. *EML4/ALK* rearrangements are mutually exclusive with *KRAS* and *EGFR* mutations.

FINAL DIAGNOSIS:

Summary Statement

The right upper lobectomy and superior segmentectomy of the right lower lobe reveals a 2.4 cm poorly differentiated mucin-producing adenocarcinoma of the right upper lobe, 2.4 cm in diameter, associated with angiolymphatic and visceral pleural invasion with involvement of the right paratracheal lymph nodes, with all margins free. Pathologic stage: T2 N2 MX.

PART 1: LYMPH NODE, INTERLOBAR LYMPH NODE, BIOPSY –

SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 2: LUNG, RIGHT UPPER LOBE AND SUPERIOR SEGMENT OF RIGHT LOWER LOBE, LOBECTOMY AND SEGMENTECTOMY –

- A. POORLY DIFFERENTIATED MUCIN PRODUCING ADENOCARCINOMA WITH FOCAL SQUAMOUS DIFFERENTIATION, DIAMETER – 2.4 CM, WITH VISCERAL PLEURAL AND ANGIOLYMPHATIC INVASION. ALL MARGINS FREE. MINIMAL HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE: T2 N2 MX.
- B. RESPIRATORY BRONCHIOLITIS WITH EMPHYSEMATOUS CHANGE.
- C. SIX (6) N1 LYMPH NODES WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY SEEN.

PART 3: LYMPH NODE, SUBCARINAL LYMPH NODE, BIOPSY –

THREE (3) FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY SEEN.

PART 4: LYMPH NODE, RIGHT PARATRACHEAL LYMPH NODE, BIOPSY –

THREE (3) OF SEVEN (7) FRAGMENTS OF LYMPH NODE WITH METASTATIC ADENOCARCINOMA WITH EXTRACAPSULAR EXTENSION.

PART 5: LYMPH NODE, RIGHT TRACHEOBRONCHIAL ANGLE, BIOPSY –

FOUR (4) FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

COMMENT:

The adenocarcinoma is an interesting one having both moderate and poorly differentiated areas, with the former characterized by cells with abundant vacuolated foamy, light eosinophilic cytoplasm surrounding pools of mucin. In some areas, psammoma bodies are identified, and in still other areas zones of solid growth are prominent. In several areas, focal squamous differentiation is seen, however, this comprises only a small percentage of the overall tumor (<10%) and therefore, we have chosen not to classify this as an adenosquamous carcinoma.

[page 2 of 2]
CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY LUNG TUMORS**

TUMOR LOCATION:	Right Upper Lobe
LUNG SEGMENT(S) INVOLVED:	Basilar
PROCEDURE:	Lobectomy
TUMOR SIZE:	Maximum dimension: 2.4 cm Minor dimension: 1.6 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive adenocarcinoma
HISTOLOGIC GRADE:	G3, Poorly differentiated
MICROSCOPIC SATELLITES:	Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL	
EXTENSION/INVASION OF TUMOR:	Visceral pleura
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	No
SURGICAL MARGIN SITE:	Distance of invasive tumor to closest margin: 8.0 mm, Bronchial margin
INFLAMMATORY(DESMOPLASTIC) REACTION:	Mild
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 7
EXTRACAPSULAR SPREAD OF N1 METASTASES:	No
N2 LYMPH NODE GROUPS INVOLVED:	Level 2R
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 3 Number of N2 lymph nodes examined: 15
EXTRACAPSULAR SPREAD OF N2 METASTASES:	Yes
UNDERLYING DISEASE(S):	Emphysema
T STAGE, PATHOLOGIC:	pT2
N STAGE, PATHOLOGIC:	pN2
M STAGE, PATHOLOGIC:	pMX
ANCILLARY STUDIES:	Histochemical stains, FISH studies, Molecular studies
Comment:	VVG stains show visceral pleural and angiolymphatic invasion. PAS, PASD and Mucicarmin stains show a focal positivity. Gram and Grocott stains for microorganisms are negative.

Source: NCI Genomic Data Commons file c597cced-135b-4cb5-815c-2d5dded6ae02 (TCGA-50-6595.13F36F42-A0D4-4CF3-B8EA-8CDEFF292A91.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).